Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4305, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4305-01A (Primary Tumor).

Diagnosis:

Total gastrectomy preparation with inclusion of a gastric carcinoma of the prepyloric antrum measuring a maximum of 3.5 cm in diameter, located on the side of the lesser curvature and extending to within a maximum 1.8 cm of the aboral duodenal resection margin and as far as the pylorus, characterized histologically as a moderately and in sections poorly differentiated adenocarcinoma. Invasive tumor spread into the outer layers of the muscularis propria.

Mucosa of antrum and corpus with non-florid, medium-grade chronic gastritis, foveolar hyperplasia, foci of intestinal metaplasia and partial atrophy of the mucosa. No evidence of *Helicobacter pylori*.

Esophageal and duodenal aboral resection margin and greater omentum tumor-free.

Two of 41 lymph nodes with metastases of the gastric carcinoma. Other lymph nodes with uncharacteristically reactive lesions.

Tumor stage: pT2a pN1 (2/41) L0 V0; G3 R0

Source: NCI Genomic Data Commons file b3ceb98f-26d7-4399-bb7a-dcb03565ee65 (TCGA-CG-4305.FCA423D4-D216-41D6-B023-5016408B7E32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).